Surgical pathology report (de-identified scan), TCGA case TCGA-61-2017, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2017-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: ADNEXA, RIGHT, SALPINGO-OOPHORECTOMY -

- A. PAPILLARY SEROUS ADENOCARCINOMA WITH PSAMMOMA BODIES FORMATION, ASSOCIATED WITH MICROPAPILLARY SEROUS TUMOR OF LOW MALIGNANT POTENTIAL .
- B. FALLOPIAN TUBE WITH PARATUBAL CYSTS.
- C. FALLOPIAN TUBE SEROSA INVOLVE BY THE SEROUS CARCINOMA

PART 2: ADNEXA, LEFT, SALPINGO-OOPHORECTOMY -

- A. PAPILLARY SEROUS ADENOCARCINOMA ASSOCIATED WITH MICROPAPILLARY SEROUS TUMOR OF LOW MALIGNANT POTENTIAL.
- B. LEFT FALLOPIAN TUBE WITH PARATUBAL CYST AND ADENOCARCINOMA CELL CLUSTER WITHIN THE LUMEN OF FALLOPIAN TUBE..
- C. MESOSALPINX AND FALLOPIAN TUBE SEROSA INVOLVED WITH PAPILLARY SEROUS ADENOCARCINOMA.

PART 3: UTERUS (250GR.), TOTAL ABDOMINAL HYSTERECTOMY -

- A. CHRONIC CERVICITIS.
- B. ATROPHIC ENDOMETRIUM.
- C. SMALL SESSILE ATROPHIC ENDOMETRIAL POLYP.
- D. EXTENSIVE ADENOMYOSIS.
- E. SEROSAL ADHESIONS WITH FOCAL PAPILLARY SEROUS CARCINOMA WITH PSAMMOMA BODIES ON SEROSAL SURFACE.

PART 4: SOFT TISSUE, SIGMOID NODULE, EXCISION -

PAPILLARY SEROUS ADENOCARCINOMA WITH PSAMMOMA BODIES AND FOCI OF SEROUS TUMOR OF LOW MALIGNANT POTENTIAL

PART 5: SOFT TISSUE, RETROPERITONEAL, EXCISION -

FIBROUS TISSUE WITH MULTIPLE PSAMMOMA BODIES WITH FOCI OF LOW MALIGNANT POTENTIAL.

PART 6: LYMPH NODE, LEFT, ILIAC, BIOPSY -

THREE LYMPH NODES NEGATIVE FOR MALIGNANCY (ZERO/THREE) (0/3).

PART 7: LYMPH NODE, PERIAORTIC, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (ZERO/ONE) (0/1).

PART 8: LYMPH NODE, ILIAC, BIOPSY -

TWO LYMPH NODES NEGATIVE FOR MALIGNANCY (ZERO/TWO) (0/2).

PART 9: LYMPH NODE, RIGHT PELVIC SIDEWALL, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR MALIGNANCY (ZERO/ONE) (0/1).

PART 10: OMENTUM, EXCISION -

OMENTAL TISSUE WITH FOCI OF PAPILLARY SEROUS ADENOCARCINOMA, CHRONIC INFLAMMATION AND MESOTHELIAL PROLIFERATION.

PART 11: SOFT TISSUE, SUBDIAPHRAGMATIC NODULE, BIOPSY -

FIBROFATTY TISSUE -METASTATIC PAPILLARY SEROUS ADENOCARCINOMA. WITH PSAMMOMA BODIES AND FIBROSIS.

PART 12: SOFT TISSUE, ASCENDING COLON, BIOPSY -

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA WITH PSAMMOMA BODIES. IN SOFT TISSUE.

Source: NCI Genomic Data Commons file bae1bfab-1e98-4dae-be71-ada079bd4e6d (TCGA-61-2017.B24757FC-4585-496E-B89E-F3DAFAC36B8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).